Surgical pathology report (de-identified scan), TCGA case TCGA-CR-7377, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-7377-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

Accession number: [REDACTED]

Final Report

DIAGNOSIS:

- 1) TONGUE MUSCLE, DEEP, EXCISION: NEGATIVE FOR MALIGNANCY.
- 2) TONGUE BASE, MUCOSAL MARGIN, EXCISION: NEGATIVE FOR MALIGNANCY.
- 3) TONGUE, ORAL MUCOSAL MARGIN, EXCISION: NEGATIVE FOR MALIGNANCY.
- 4) PHARYNGEAL WALL, SUPERIOR MARGIN, EXCISION: NEGATIVE FOR MALIGNANCY.
- 5) FLOOR OF MOUTH, MUCOSAL MARGIN, EXCISION: NEGATIVE FOR MALIGNANCY;
FRAGMENT OF BENIGN LYMPHOID TISSUE.
- 6) LYMPH NODE, LEFT LEVEL 1, EXCISION: 1 OF 3 LYMPH NODES INVOLVED BY
CARCINOMA (NODE ENTIRELY REPLACED BY CARCINOMA); ADDITIONAL SOFT TISSUE
DEPOSIT OF CARCINOMA PRESENT; BENIGN SALIVARY TISSUE.
- 7) LYMPH NODE, LEFT LEVEL 2, EXCISION: 1 OF 1 LYMPH NODES INVOLVED BY
CARCINOMA, 4.0 CM IN GREATEST DIMENSION (GROSS MEASUREMENT) WITH EXTRANODAL
EXTENSION PRESENT.
- 8) LYMPH NODE, LEFT LEVEL 3, EXCISION: 5 LYMPH NODES, NEGATIVE FOR
MALIGNANCY.
- 9) LYMPH NODE, LEFT LEVEL 4, EXCISION: 4 LYMPH NODES, NEGATIVE FOR
MALIGNANCY.
- 10) SALIVARY GLAND, RIGHT LEVEL 1, EXCISION: SALIVARY TISSUE, NEGATIVE FOR
MALIGNANCY; NO LYMPHOID TISSUE IDENTIFIED.
- 11) LYMPH NODE, RIGHT LEVEL 2, EXCISION: 1 OF 12 LYMPH NODES INVOLVED BY
CARCINOMA.
- 12) LYMPH NODE, RIGHT LEVEL 3, EXCISION: 4 LYMPH NODES, NEGATIVE FOR
MALIGNANCY.
- 13) TONGUE, TONSILLAR PILLAR/FLOOR OF MOUTH, EXCISION: MODERATE TO POORLY
DIFFERENTIATED SQUAMOUS CELL CARCINOMA, (SIMILAR TO PREVIOUS [REDACTED]),
4.0 CM IN GREATEST DIMENSION, INVOLVING MULTIPLE INKED UNORIENTED MARGINS;
EXTENSIVE PERINEURAL INVASION IDENTIFIED; LYMPHOVASCULAR INVASION
IDENTIFIED (SEE COMMENT).

COMMENT: These findings correspond to AJCC Pathologic Stage IVA (pT4a,
pN2c, pM n/a).

[page 2 of 5]
CLINICAL DATA

Clinical Features: Unspecified

Operator: Dr. [REDACTED]

Operation: Unspecified

Operative Findings: Unspecified

Operative Diagnosis: Unspecified

Tissue Submitted: 1)deep tongue muscle; 2)tongue base mucosal margin; 3)oral tongue mucosal margin; 4)pharyngeal wall superior margin; 5)floor of mouth mucosal margin; 6)lymph node left level 1; 7) lymph node, left level 2; 8) lymph node, left level 3; 9) lymph node, left level 4; 10) lymph node, right level 1; 11) lymph node, right level 2; 12)lymph node, right level 3; 13)tongue, tonsil pilar floor of mouth

GROSS DESCRIPTION:

1) SOURCE: Tongue - Deep, Muscle

The specimen labeled "deep tongue mucosal margin" is received fresh for intraoperative consultation and consists of a 1.0 x 0.4 x 0.3 cm of yellow-tan glistening tissue. The sample is submitted entirely for frozen section analysis.

Summary of sections: 1AFSC, 1/1.

2) SOURCE: Tongue - Base, Mucosal Margin

The specimen labeled "base of tongue, mucosal margin" is received fresh for intraoperative consultation and consists of a 5.0 x 0.8 x 0.3 cm piece of tan-yellow, glistening tissue with the anterior surface marked in blue ink. The sample is submitted entirely submitted for frozen section analysis.

Summary of sections: 2AFSC, 1/1.

3) SOURCE: Tongue - Oral, Mucosal Margin

The specimen labeled "oral tongue mucosal margin" is received fresh for intraoperative consultation and consists of a 2.1 x 0.7 x 0.3 cm piece of tan-yellow, smooth glistening tissue with the anterior surface marked with blue ink. The sample is entirely submitted for frozen section analysis.

Summary of sections: 3AFSC, 1/1.

4) SOURCE: Pharyngeal Wall Superior Margin

The specimen labeled "pharyngeal wall margin" is received fresh for intraoperative consultation and consists of a 0.3 x 0.3 x 0.2 cm piece of

[page 3 of 5]
tan, smooth glistening tissue with the superior margin inked in blue. The sample is entirely submitted for frozen section analysis.

Summary of sections: 4AFSC, 1/1.

5) SOURCE: Floor of Mouth Mucosal Margin

The specimen labeled "floor of mouth mucosal margin" is received fresh for intraoperative consultation and consists of a 4.0 x 0.3 x 0.2 cm piece of tan, smooth glistening tissue with the anterior surface marked with blue ink. The sample is submitted entirely for frozen section analysis.

Summary of sections: 5AFSC, 1/1.

6) SOURCE: Lymph node, Left Level 1

The specimen labeled "left neck level 1" is received fresh and consists of a 6.5 x 5.0 x 2.3 cm piece of tissue that is red-tan and contains lobulated fibroadipose tissue. There are several staples and one suture mark present. The sample is received unoriented. There are two firm nodules present. The first measures 3.0 x 1.0 x 1.2 cm and the second measures 0.9 x 0.7 x 0.7 cm. Serially sectioning of the nodule reveals a white, fibrous interior.

Representative sections are submitted.

Summary of sections: 6A, section of largest nodule, 2/1; 6B, representative sections of candidate lymph node #2, 3/1; 6C, representative sections of candidate lymph nodes, 4/1.

7) SOURCE: Lymph node, Left Level 2

The specimen labeled "level 2" is received fresh and consists of a 5.5 x 4.0 x 2.0 cm piece of red-tan glistening tissue with attached lobulated fibroadipose tissue. There are multiple staples present. There is a firm nodule measuring 4.0 x 1.5 x 1.5 cm. Serial sectioning of the nodule reveals a white-tan fibrous interior. Representative sections are submitted.

Summary of sections: 7A, representative section of nodule, 1/1; 7B, representative section of fibroadipose tissue with lymph node candidate, 1/1.

8) SOURCE: Lymph node, Left Level 3

The specimen labeled "left level 3" is received fresh and consists of a 14.5 x 1.0 x 0.8 cm piece of tissue with two distinct areas. The first is consistent with muscle measuring 5.5 cm in length and the second is 9.5 cm in length. No discrete nodules are palpated. The sample is smooth, glistening and tan-yellow in appearance.

Summary of sections: 8A, candidate lymph nodes, 4/1.

9) SOURCE: Lymph node, Left Level 4

The specimen labeled, "left level 4," is received fresh and consists of a 5.5 x 5.0 x 0.6 cm piece of tissue that is yellow-tan, smooth, and glistening, consistent with lobulated, fibroadipose tissue. No discrete nodules or lesions are palpated. The specimen is serially sectioned and representative sections are submitted.

Summary of sections: 9A, candidate lymph nodes, 4/1.

[page 4 of 5]
10) SOURCE: Lymph node, Right Level 1

"The specimen labeled, "right level 1," is received fresh and consists of a 5.5 x 3.3 x 1.8 cm fragment of smooth, and glistening, pink and tan, lobulated, fibroadipose tissue and several adherent staples. The specimen is serially sectioned and representative sections are submitted.

Summary of sections: 10A-B, candidate lymph nodes, 3/1 each.

11) SOURCE: Lymph node, Right Level 2

The specimen labeled, "right level 2," is received fresh and consists of a 4.0 x 3.5 x 0.5 cm piece of tissue that is yellow-pink, smooth, and glistening with no discrete nodules palpated. Representative sections are submitted.

Summary of sections: 11A-B, candidate lymph nodes, 4/1 each.

12) SOURCE: Lymph node, Right Level 3

The specimen labeled, "right level 3," is received fresh and consists of a 4.0 x 2.0 x 0.5 cm segment of tan-yellow tissue, consistent with yellow, lobulated, fibroadipose tissue. There are no discrete nodules or lesions. Representative sections are submitted.

Summary of sections: 12A, four candidate lymph nodes, 4/1.

13) SOURCE: Tongue, Tonsillar Pillar, Floor of Mouth

The specimen labeled, "tongue, tonsillar pillar, floor of mouth," is received fresh and consists of a segment of tongue with surrounding connective tissue. The sample measures 6.5 cm in the anterior to posterior dimension, 3.5 cm medial to lateral, and 6.0 cm superior to inferior. There is a suture in the anterior tongue. The sample is not oriented per requisition only. There are two areas of induration in the tongue. The first measures 2.2 cm and is a triangular-shaped wedge; the specimen was received in this manner. The second is a 3.5 x 0.6 x 0.4 cm area where tissue is submitted for research. The surface of the tongue is tan to pink with multiple papillae. There is an ill-defined nodule on the posterior surface, measuring 4.0 x 3.5 x 1.0 cm. The specimen is inked as follows: deep inferior margin-black (this contains the hyoid bone), posterior margin-green, medial margin-red, lateral margin-blue. Buccal mucosa inferior to the tongue and is smooth, tan, and glistening. The specimen is sectioned anterior to posterior, perpendicular to the long axis of the tongue. The superior surface is not inked. The specimen is submitted for research, in glutaraldehyde, in -80 degree freezer and in RPMI.

Summary of sections: 13A, section of nodule on posterior tongue with surface of tongue, 1/1; 13B, representative section of lateral margin, 2/1; 13C, inferior and lateral margins, 1/1; 13D, representative section of medial and posterior margin, 1/1; 13E, section of tongue with posterior margin, 1/1; 13F, section of tongue with medial margin, 1/1; 13G, /1.

Dictated by [REDACTED]

Dictated by [REDACTED]

Slides and report reviewed by Attending Pathologist.

[page 5 of 5]
SURGICAL PATHOLOGY INTRAOPERATIVE CONSULTATION

1) SOURCE: Tongue - Deep, Muscle

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

2) SOURCE: Tongue - Base, Mucosal Margin

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

3) SOURCE: Tongue - Oral, Mucosal Margin

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

4) SOURCE: Pharyngeal Wall Superior Margin

FROZEN SECTION DIAGNOSIS: BENIGN. [REDACTED]

5) SOURCE: Floor of Mouth Mucosal Margin

FROZEN SECTION DIAGNOSIS: BENIGN. R [REDACTED]

Electronically signed by: [REDACTED]

Source: NCI Genomic Data Commons file c6d3c72b-9d1b-4e8d-8af9-29cbc9e79837 (TCGA-CR-7377.5039123A-176A-4817-A91D-130F7E34B938.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).